Somatic mutation profile of tumor specimen 0DHQF4 from CCDI case PBBUMA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,126 days).
Specimen 0DHQF4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 366b02c9-253f-427f-9654-dc0ff8d3fbc9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHQDK (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3f54e46-77ad-4c88-b91c-1605c9261ccc

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR5 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 54/414 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs78656585, COSV54760551; called by muse, mutect2, varscan2
- C20orf27 | c.146G>A p.S49N (on ENST00000379772 / NM_001258429.2; = p.S74N on NM_001039140.3) | Missense Mutation (SNP) | VAF 107/321 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs753933743; called by muse, mutect2, varscan2
- MAGEB6 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 298/354 reads (84%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); catalogued as rs776261244, COSV100983726, COSV66872916; called by muse, mutect2, varscan2
- UBASH3A | c.1948G>A p.A650T | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs762893914, COSV52313062; called by muse, mutect2, varscan2
- AHNAK2 | c.11203G>A p.D3735N | Missense Mutation (SNP) | VAF 19/642 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- TRPM3 | c.3832G>A p.E1278K (on ENST00000357533 / NM_001366142.2; = p.E1133K on NM_020952.6) | Missense Mutation (SNP) | VAF 204/353 reads (58%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CREBBP | c.1764A>G p.V588= | Silent (SNP) | VAF 53/525 reads (10%) | called by muse, mutect2, varscan2
- EDC4 | c.3115C>T p.L1039= | Silent (SNP) | VAF 42/394 reads (11%) | called by muse, mutect2, varscan2
- OR2T4 | c.252C>T p.D84= | Silent (SNP) | VAF 74/1472 reads (5%) | catalogued as rs745887066, COSV63543568; called by muse, mutect2
